Somatic mutation profile of tumor specimen C3N-02030-03 (aliquot CPT0133780089) from CPTAC case C3N-02030, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.7 years (22,893 days).
Specimen C3N-02030-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 159c2fab-3167-4370-bad6-6dbd52b7b47b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02030-71 (Blood Derived Normal), aliquot CPT0133880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db2df522-eac6-4872-9797-d636817262fd

The open-access MAF lists 591 somatic variants for this specimen: 409 protein-altering or splice-affecting, 110 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 274, Silent 110, Frame Shift Del 79, Intron 43, Frame Shift Ins 26, Nonsense Mutation 16, 3'UTR 10, 5'UTR 8, Splice Site 5, In Frame Del 5, 3'Flank 4, RNA 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 119/320 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 65/130 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 152/371 reads (41%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- PARK7 | c.189del p.E64Rfs*25 | Frame Shift Del (DEL) | VAF 120/332 reads (36%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, varscan2
- PRPF6 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 106/271 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs387907100, CM112959, COSV53868700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 49/168 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs876659443, CM110119, COSV64289131, COSV64291926, COSV64310633; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 186/372 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TECTA | c.5977C>T p.R1993* | Nonsense Mutation (SNP) | VAF 101/240 reads (42%) | catalogued as rs760574657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USP9X | c.2224C>T p.R742* | Nonsense Mutation (SNP) | VAF 48/113 reads (42%) | catalogued as rs1555924860, COSV100199662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs755655007, COSV99367987; called by muse, mutect2, varscan2
- ABCA8 | c.4036G>A p.V1346M | Missense Mutation (SNP) | VAF 79/151 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs767871494, COSV52201017; called by muse, mutect2, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 62/203 reads (31%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- ABCC1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs756648375; called by muse, mutect2, varscan2
- ADAMTS16 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484616740, COSV56997505; called by muse, mutect2, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 152/255 reads (60%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AKAP8 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs537526016; called by muse, mutect2, varscan2
- AKAP9 | c.116dup p.R40Efs*7 | Frame Shift Ins (INS) | VAF 66/249 reads (27%) | catalogued as rs765201611; called by mutect2, varscan2
- ALDH7A1 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 128/322 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as CM121731; called by muse, mutect2, varscan2
- AOX1 | c.1666C>A p.L556I | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs769661664; called by muse, mutect2, varscan2
- APOA5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 216/571 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM120394; called by muse, mutect2, varscan2
- ATP2B3 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 135/386 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99051133; called by muse, mutect2, varscan2
- AZU1 | c.483del p.R162Vfs*11 | Frame Shift Del (DEL) | VAF 91/219 reads (42%) | catalogued as rs772652509, COSV99297150; called by mutect2, pindel, varscan2
- B3GAT1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs763308287; called by muse, mutect2, varscan2
- BMPR1B | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373000965; called by muse, mutect2, varscan2
- BRD2 | c.1932C>A p.Y644* | Nonsense Mutation (SNP) | VAF 103/321 reads (32%) | catalogued as COSV100875888; called by muse, mutect2, varscan2
- CACNA1B | c.4336G>A p.A1446T | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs200865012; called by muse, mutect2, varscan2
- CACNB1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs753711036; called by muse, mutect2, varscan2
- CACYBP | c.432del p.V145Sfs*22 | Frame Shift Del (DEL) | VAF 27/150 reads (18%) | catalogued as rs1161545619; called by mutect2, pindel, varscan2
- CCDC190 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 95/392 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs373634463; called by muse, mutect2, varscan2
- CCDC43 | c.646dup p.R216Kfs*61 | Frame Shift Ins (INS) | VAF 38/90 reads (42%) | catalogued as rs751135235; called by mutect2, varscan2
- CEBPA | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 221/594 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781549846; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 16/78 reads (21%) | catalogued as rs768479535; called by pindel, varscan2
- CFAP206 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs1333669635; called by muse, mutect2, varscan2
- CLDN12 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 128/341 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV55307631; called by muse, mutect2, varscan2
- CLEC18A | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 4/348 reads (1%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs764034494; called by muse, mutect2
- COL14A1 | c.1321+1G>A p.X441_splice | Splice Site (SNP) | VAF 30/94 reads (32%) | catalogued as rs775204866, COSV52852671; called by muse, mutect2, varscan2
- COL27A1 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs781277879, COSV61925278; called by muse, mutect2, varscan2
- COL7A1 | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 174/454 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778104401; called by muse, mutect2, varscan2
- COL8A1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs558799692; called by muse, mutect2, varscan2
- CPAMD8 | c.1994C>T p.A665V (on ENST00000651564; = p.A618V on NM_015692.5) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV52234755; called by muse, mutect2, varscan2
- CPSF6 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as rs753465837; called by muse, mutect2, varscan2
- CREM | c.364A>G p.R122G (on ENST00000429130; = p.R73G on NM_001881.3) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188189426; called by muse, mutect2, varscan2
- CRISPLD2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 112/278 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs372363505; called by muse, mutect2, varscan2
- CSMD1 | c.9422G>A p.R3141H (on ENST00000520002; = p.R3140H on NM_033225.6) | Missense Mutation (SNP) | VAF 88/203 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs768149539, COSV59277588; called by muse, mutect2, varscan2
- CTU1 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 31/452 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70292317; called by muse, mutect2
- CYP2D7 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 80/373 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs764888846; called by muse, mutect2, varscan2
- D2HGDH | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1472114573, COSV58319342; called by muse, mutect2, varscan2
- DBH | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 179/474 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs199566547; called by muse, mutect2, varscan2
- DCAF13 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs868133848; called by muse, mutect2, varscan2
- DCHS1 | c.4222C>T p.R1408C | Missense Mutation (SNP) | VAF 180/395 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs772193454; called by muse, mutect2, varscan2
- DKK4 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs764520274, COSV55183577; called by muse, mutect2, varscan2
- DLEC1 | c.3314C>T p.A1105V | Missense Mutation (SNP) | VAF 108/322 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs780446743, COSV57300501; called by muse, mutect2, varscan2
- DMBT1 | c.7462C>T p.R2488C (on ENST00000338354 / NM_001377530.1; = p.R1731C on NM_004406.3) | Missense Mutation (SNP) | VAF 154/574 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1437407547; called by muse, mutect2, varscan2
- DOCK5 | c.966del p.F322Lfs*5 | Frame Shift Del (DEL) | VAF 46/123 reads (37%) | catalogued as rs36119599; called by mutect2, pindel, varscan2
- DRC1 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV56536356; called by muse, mutect2
- DRC3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs757392054; called by muse, mutect2, varscan2
- DSCAM | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.788); catalogued as rs367647810, COSV101259937; called by muse, mutect2, varscan2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 44/122 reads (36%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- EML3 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1465554218; called by muse, mutect2, varscan2
- EP400 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs200859619; called by muse, mutect2, varscan2
- FAM131B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 171/448 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs759366087, COSV58367322, COSV58375458; called by muse, mutect2, varscan2
- FAM186A | c.5432C>T p.A1811V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs765273273; called by muse, mutect2, varscan2
- FEV | c.704dup p.H236Pfs*18 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | catalogued as rs141171754; called by mutect2, pindel, varscan2
- FKBP8 | c.779C>T p.T260M (on ENST00000222308 / NM_001308373.2; = p.T261M on NM_012181.5) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV55893476; called by muse, mutect2, varscan2
- FLNC | c.4480C>T p.R1494W | Missense Mutation (SNP) | VAF 238/715 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs779079128, COSV100367757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXC2 | c.275_277del p.K92del | In Frame Del (DEL) | VAF 296/800 reads (37%) | catalogued as rs1203250715; called by pindel, varscan2
- FOXD3 | c.1178G>A p.G393D | Missense Mutation (SNP) | VAF 82/203 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.074); catalogued as rs943720041; called by muse, mutect2, varscan2
- FOXE1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64300120; called by muse, mutect2, varscan2
- FRMPD4 | c.3313del p.S1105Vfs*3 | Frame Shift Del (DEL) | VAF 124/363 reads (34%) | catalogued as rs35659462; called by mutect2, pindel, varscan2
- FSD2 | c.1646del p.G549Afs*4 | Frame Shift Del (DEL) | VAF 53/227 reads (23%) | catalogued as rs1246402267; called by mutect2, pindel, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 38/100 reads (38%) | catalogued as rs749150409; called by mutect2, varscan2
- GOLGA1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1394891575; called by muse, mutect2, varscan2
- GPAT2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752511500; called by muse, mutect2, varscan2
- GPR137B | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 69/392 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs147078955; called by muse, mutect2, varscan2
- HINT2 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV52413989; called by muse, mutect2
- HNRNPA1 | c.18T>G p.S6= | Splice Region (SNP) | VAF 45/105 reads (43%) | catalogued as rs755898648; called by muse, mutect2, varscan2
- HSPA12A | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781809567; called by muse, mutect2, varscan2
- INPP4A | c.2930C>T p.T977M (on ENST00000074304 / NM_001134224.1; = p.T938M on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559132688, COSV50789938; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 29/101 reads (29%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- ISLR2 | c.934A>T p.T312S | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.482); catalogued as rs1435695204; called by muse, mutect2
- ITGB6 | c.2330G>A p.R777K | Missense Mutation (SNP) | VAF 95/241 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51791808, COSV51798615; called by muse, mutect2, varscan2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 28/79 reads (35%) | catalogued as rs755650243; called by mutect2, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 78/203 reads (38%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KDM6A | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65040820; called by muse, mutect2, varscan2
- KHDC1 | c.581G>A p.S194N (on ENST00000370384 / NM_001251874.2; = p.S121N on NM_030568.5) | Missense Mutation (SNP) | VAF 114/285 reads (40%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.916); catalogued as rs962762004, COSV57615383; called by muse, mutect2, varscan2
- KLHL26 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.351); catalogued as rs749078539; called by muse, mutect2
- KMT2B | c.7030G>A p.A2344T | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755245377; called by muse, mutect2, varscan2
- KMT2D | c.10744C>T p.R3582W | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56491153; called by muse, mutect2, varscan2
- KMT2D | c.5927C>T p.S1976L | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV56468464; called by muse, mutect2, varscan2
- LAGE3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV62074504; called by muse, mutect2, varscan2
- LANCL2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 122/345 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as rs770121457, COSV54649883; called by muse, mutect2, varscan2
- LILRB5 | c.1526G>A p.G509D (on ENST00000449561 / NM_001081442.3; = p.G508D on NM_006840.5) | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV60260780; called by muse, mutect2, varscan2
- LTB | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs567302751, COSV53000420; called by muse, mutect2, varscan2
- MAGIX | c.958dup p.A320Gfs*88 | Frame Shift Ins (INS) | VAF 42/158 reads (27%) | catalogued as rs1321319432; called by mutect2, pindel, varscan2
- MAML3 | c.2426A>G p.Q809R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs1171552463; called by muse, mutect2, varscan2
- MAN2C1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 123/276 reads (45%) | catalogued as COSV99145269; called by muse, mutect2, varscan2
- MRC2 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 99/300 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57640762; called by muse, mutect2, varscan2
- MTERF3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs750850029; called by muse, mutect2, varscan2
- MYEOV | c.869del p.P290Qfs*48 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as COSV58294423; called by mutect2, pindel
- MYLK | c.4813G>T p.D1605Y | Missense Mutation (SNP) | VAF 175/461 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60610051; called by muse, mutect2, varscan2
- NAE1 | c.1102A>G p.I368V | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51975146; called by muse, mutect2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 39/182 reads (21%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NFX1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 31/110 reads (28%) | catalogued as rs1451971621; called by muse, mutect2, varscan2
- NOTCH1 | c.3179T>C p.V1060A | Missense Mutation (SNP) | VAF 210/533 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53082811; called by muse, mutect2, varscan2
- NRROS | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751058757, COSV60744792; called by muse, mutect2, varscan2
- ODF3L2 | c.49dup p.L17Pfs*62 | Frame Shift Ins (INS) | VAF 32/106 reads (30%) | catalogued as rs748636054; called by mutect2, pindel, varscan2
- OGA | c.1578del p.M527Cfs*27 | Frame Shift Del (DEL) | VAF 102/440 reads (23%) | catalogued as COSV63382218; called by mutect2, pindel, varscan2
- OGFOD3 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 119/304 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs756501679, COSV57339492; called by muse, mutect2, varscan2
- OR12D2 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs752585138, COSV65828725; called by muse, mutect2, varscan2
- OR13G1 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 68/332 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1558292655; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 89/475 reads (19%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2A12 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 130/402 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs749726901, COSV68822033; called by muse, mutect2, varscan2
- OR52D1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 110/290 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760829167, COSV59487388; called by muse, mutect2, varscan2
- OR5B2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs199556711; called by muse, mutect2, varscan2
- OR6C4 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs750194566; called by muse, mutect2, varscan2
- OTUD7B | c.1976del p.G659Vfs*169 | Frame Shift Del (DEL) | VAF 52/266 reads (20%) | catalogued as COSV100967422; called by mutect2, pindel, varscan2
- PARD3B | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV62502529; called by muse, mutect2, varscan2
- PAX5 | c.76dup p.V26Gfs*49 | Frame Shift Ins (INS) | VAF 50/162 reads (31%) | catalogued as rs767894241; called by mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 29/84 reads (35%) | catalogued as rs753190856; called by mutect2, varscan2
- PBRM1 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs115997236; called by muse, mutect2, varscan2
- PCDHA5 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 153/420 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as COSV65352687, COSV65353320, COSV65354029; called by muse, varscan2
- PCLO | c.8192G>A p.R2731H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200140697, COSV61622195; called by muse, mutect2, varscan2
- PCLO | c.7265del p.P2422Lfs*22 | Frame Shift Del (DEL) | VAF 43/114 reads (38%) | catalogued as rs1262793592; called by mutect2, pindel, varscan2
- PDE2A | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs138870390, COSV57811844; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 44/106 reads (42%) | catalogued as rs759495724; called by mutect2, varscan2
- PGAP6 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 108/367 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758802749; called by muse, mutect2
- PHACTR4 | c.2032G>T p.E678* (on ENST00000373839 / NM_001350159.2; = p.E688* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 32/112 reads (29%) | catalogued as COSV65783415, COSV65785417; called by muse, mutect2, varscan2
- PI4KA | c.5219A>G p.K1740R | Missense Mutation (SNP) | VAF 24/357 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs1390556648, COSV55402756; called by muse, mutect2
- PI4KA | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1460046498, COSV55412316, COSV55422086; called by muse, mutect2, varscan2
- PIAS4 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 98/275 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs765883460; called by muse, mutect2, varscan2
- PIK3C2B | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs373236355; called by muse, mutect2, varscan2
- PKP3 | c.2260_2262del p.K754del | In Frame Del (DEL) | VAF 42/137 reads (31%) | catalogued as rs755089774; called by pindel, varscan2
- PLEKHM1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 102/377 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251964349, COSV69598825; called by muse, mutect2, varscan2
- PMFBP1 | c.929A>G p.H310R | Missense Mutation (SNP) | VAF 86/198 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.528); catalogued as rs1480138422; called by muse, mutect2, varscan2
- POLK | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.755); catalogued as COSV99605417; called by muse, mutect2
- POLR3GL | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs370170498; called by muse, mutect2, varscan2
- PPP4R2 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1230961376; called by muse, mutect2, varscan2
- PRDM13 | c.1869C>A p.H623Q | Missense Mutation (SNP) | VAF 270/657 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375460946; called by muse, mutect2, varscan2
- PTH1R | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 208/523 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752454624, COSV57315208; called by muse, mutect2, varscan2
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 50/159 reads (31%) | catalogued as rs1234606471; called by mutect2, varscan2
- RASSF4 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.065); catalogued as rs748139811; called by muse, mutect2, varscan2
- RDH11 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as rs563954790, COSV101191426; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 26/60 reads (43%) | catalogued as rs751982308; called by mutect2, varscan2
- RNF39 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.94); PolyPhen benign (0.134); catalogued as rs773266930; called by muse, mutect2, varscan2
- RPL7L1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100491742; called by muse, mutect2, varscan2
- RXFP1 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs776423555; called by muse, mutect2, varscan2
- SALL2 | c.1586del p.P529Qfs*22 | Frame Shift Del (DEL) | VAF 39/114 reads (34%) | catalogued as rs755171367; called by mutect2, pindel, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 26/60 reads (43%) | catalogued as rs763290832; called by mutect2, varscan2
- SCNN1D | c.53del p.G18Afs*179 (on ENST00000338555; = p.A151Lfs*18 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs1270083658; called by mutect2, pindel
- SIGLEC12 | c.622C>A p.P208T (on ENST00000291707 / NM_053003.4; = p.P90T on NM_033329.2) | Missense Mutation (SNP) | VAF 128/292 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52463588; called by muse, mutect2, varscan2
- SIPA1 | c.748_750del p.K250del | In Frame Del (DEL) | VAF 43/110 reads (39%) | catalogued as rs1333397145; called by mutect2, pindel, varscan2
- SKIV2L | c.1637del p.G546Afs*83 | Frame Shift Del (DEL) | VAF 11/23 reads (48%) | catalogued as COSV64814087; called by mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 69/312 reads (22%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC2A11 | c.895G>A p.V299M (on ENST00000345044 / NM_001024938.4; = p.V306M on NM_030807.5) | Missense Mutation (SNP) | VAF 108/306 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs773866178; called by muse, mutect2, varscan2
- SLC43A2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 95/210 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); catalogued as rs746970383; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 36/81 reads (44%) | catalogued as rs763364024; called by mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 48/243 reads (20%) | catalogued as rs1466680694; called by mutect2, pindel, varscan2
- SPATC1L | c.580C>T p.R194C (on ENST00000291672 / NM_001142854.2; = p.R40C on NM_032261.5) | Missense Mutation (SNP) | VAF 113/295 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751537273; called by muse, mutect2, varscan2
- SPEF2 | c.877dup p.I293Nfs*6 | Frame Shift Ins (INS) | VAF 59/186 reads (32%) | catalogued as rs1390109415; called by mutect2, varscan2
- SPEN | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 175/413 reads (42%) | catalogued as rs1307834195, COSV65365281; called by muse, mutect2, varscan2
- SPEN | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); catalogued as rs763959899, COSV65359777; called by muse, mutect2, varscan2
- SPSB4 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776085694, COSV60150454; called by muse, mutect2, varscan2
- SPTA1 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 120/604 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs752468147; called by muse, mutect2, varscan2
- SPTBN5 | c.5171G>A p.R1724Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs199701887; called by muse, mutect2, varscan2
- SRRM1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.53); catalogued as rs1266741422; called by muse, mutect2, varscan2
- SRRM4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 89/241 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs377333031; called by muse, mutect2, varscan2
- TAX1BP1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV55292174; called by muse, mutect2
- TBL2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 11/344 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782679561; called by muse, mutect2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 28/90 reads (31%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 72/156 reads (46%) | catalogued as rs748021112; called by mutect2, varscan2
- TDRKH | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 48/360 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767475622, COSV58617972; called by muse, mutect2, varscan2
- TENT5B | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56693344; called by mutect2, varscan2
- TET2 | c.2511T>A p.N837K | Missense Mutation (SNP) | VAF 133/367 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755404521; called by muse, mutect2, varscan2
- TFCP2L1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 104/246 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55292626; called by muse, mutect2, varscan2
- TMEM184B | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 109/307 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62672464; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 69/182 reads (38%) | catalogued as rs770800449; called by mutect2, varscan2
- TRAV3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 103/279 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs745851436; called by muse, mutect2, varscan2
- TRIM2 | c.1087G>A p.A363T (on ENST00000437508; = p.A390T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs754123914; called by muse, mutect2, varscan2
- TRIM31 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs928628355; called by muse, mutect2, varscan2
- TRIM9 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 161/398 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV100030317; called by muse, mutect2, varscan2
- TRPV1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903705338, COSV51518182; called by muse, mutect2, varscan2
- TUBA3D | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.203); catalogued as rs745718611, COSV58312359; called by muse, mutect2, varscan2
- USP33 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs749382743, COSV62468280; called by muse, mutect2, varscan2
- UVRAG | c.1777C>T p.R593W | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs759030935; called by muse, mutect2
- VANGL2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 87/378 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.144); catalogued as COSV100925573; called by muse, mutect2, varscan2
- WDFY4 | c.7295G>A p.C2432Y | Missense Mutation (SNP) | VAF 81/342 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1214976776; called by muse, mutect2, varscan2
- XIRP1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775595813, COSV100453679; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 145/446 reads (33%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBED2 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); catalogued as COSV51920425; called by mutect2, varscan2
- ZBED8 | c.894_897del p.N299Sfs*21 | Frame Shift Del (DEL) | VAF 78/191 reads (41%) | catalogued as rs1184980267; called by mutect2, pindel, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 46/131 reads (35%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZKSCAN2 | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV60156375; called by muse, mutect2, varscan2
- ZNF496 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as rs758982919, COSV54175637; called by muse, mutect2, varscan2
- ZNF512B | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs768660385, COSV53871876; called by muse, mutect2, varscan2
- ZNF697 | c.1547del p.T516Rfs*66 | Frame Shift Del (DEL) | VAF 106/296 reads (36%) | catalogued as COSV70284359; called by mutect2, pindel, varscan2
- ABCB8 | c.1193G>A p.G398D (on ENST00000297504 / NM_001282291.2; = p.G381D on NM_007188.5) | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACAP3 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 214/579 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACBD3 | c.328T>A p.L110M | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTN4 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 167/443 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM21 | c.902del p.N301Ifs*4 | Frame Shift Del (DEL) | VAF 69/196 reads (35%) | called by mutect2, varscan2
- ADAM30 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADCY3 | c.2186A>G p.Q729R | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.046); called by muse, varscan2
- AHRR | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AKAP9 | c.6111dup p.L2038Tfs*8 (on ENST00000359028; = p.L2006Tfs*8 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 32/104 reads (31%) | called by mutect2, pindel, varscan2
- AOC3 | c.957A>C p.Q319H | Missense Mutation (SNP) | VAF 139/324 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- APBA2 | c.1918-1G>T p.X640_splice | Splice Site (SNP) | VAF 152/512 reads (30%) | called by muse, mutect2, varscan2
- APBB2 | c.1553A>T p.K518I (on ENST00000295974 / NM_001166050.2; = p.K519I on NM_004307.2) | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ARAP3 | c.1180del p.R394Dfs*21 | Frame Shift Del (DEL) | VAF 102/274 reads (37%) | called by mutect2, pindel, varscan2
- ARID1A | c.4899del p.M1634* | Frame Shift Del (DEL) | VAF 38/95 reads (40%) | called by mutect2, pindel, varscan2
- ARID5A | c.1772dup p.N591Kfs*33 | Frame Shift Ins (INS) | VAF 64/199 reads (32%) | called by mutect2, pindel, varscan2
- ATP13A3 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ATP2B1 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP2B4 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 59/247 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- BAIAP2L1 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- BSCL2 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 160/446 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- C16orf89 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CATSPERE | c.1551A>G p.I517M | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBX2 | c.977dup p.H329Afs*84 | Frame Shift Ins (INS) | VAF 47/125 reads (38%) | called by mutect2, pindel, varscan2
- CCDC85C | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 127/313 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CD6 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 83/272 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CDH17 | c.1504del p.V502Lfs*13 | Frame Shift Del (DEL) | VAF 37/101 reads (37%) | called by mutect2, pindel, varscan2
- CEACAM19 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP78 | c.904A>G p.M302V | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CFAP61 | c.2908A>G p.N970D | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- CHST7 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 144/318 reads (45%) | called by muse, mutect2, varscan2
- CILP2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- CMIP | c.805C>T p.R269* (on ENST00000537098 / NM_198390.2; = p.R175* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 60/181 reads (33%) | called by muse, mutect2, varscan2
- CNOT1 | c.6575T>G p.F2192C | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- COCH | c.1267T>C p.C423R (on ENST00000216361 / NM_001347720.1; = p.C358R on NM_004086.3) | Missense Mutation (SNP) | VAF 159/342 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COX10 | c.1115_1116insA p.V373Cfs*92 | Frame Shift Ins (INS) | VAF 91/254 reads (36%) | called by mutect2, pindel, varscan2
- CRAMP1 | c.1938dup p.A647Rfs*29 | Frame Shift Ins (INS) | VAF 54/180 reads (30%) | called by mutect2, pindel, varscan2
- CRHR2 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 112/261 reads (43%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CRY2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CSMD2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CSMD3 | c.9577C>T p.Q3193* (on ENST00000297405 / NM_001363185.1; = p.Q3024* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 96/246 reads (39%) | called by muse, mutect2, varscan2
- CYTH2 | c.1134C>A p.D378E (on ENST00000427476; = p.D377E on NM_004228.7) | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- DAAM1 | c.2663+4_2663+7del p.X888_splice | Splice Site (DEL) | VAF 22/70 reads (31%) | called by pindel, varscan2
- DCHS1 | c.2618del p.P873Qfs*5 | Frame Shift Del (DEL) | VAF 115/352 reads (33%) | called by mutect2, pindel, varscan2
- DDR2 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 110/546 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DMTF1 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 101/333 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH1 | c.11242C>T p.H3748Y | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DNAJB11 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DNHD1 | c.5237C>T p.P1746L | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK2 | c.144C>A p.Y48* | Nonsense Mutation (SNP) | VAF 39/147 reads (27%) | called by muse, mutect2, varscan2
- DPH2 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- E2F8 | c.1433del p.P478Qfs*2 | Frame Shift Del (DEL) | VAF 98/277 reads (35%) | called by mutect2, pindel, varscan2
- ECHDC1 | c.136del p.T46Hfs*24 (on ENST00000531967 / NM_001139510.1; = p.T40Hfs*24 on NM_018479.3) | Frame Shift Del (DEL) | VAF 100/264 reads (38%) | called by mutect2, pindel, varscan2
- EHF | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ELAPOR2 | c.833del p.N278Ifs*47 (on ENST00000450689 / NM_001142749.3; = p.N111Ifs*47 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 35/97 reads (36%) | called by mutect2, pindel, varscan2
- EP400 | c.3949C>T p.H1317Y | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ERICH3 | c.2296del p.T766Rfs*23 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | called by mutect2, pindel, varscan2
- ESYT1 | c.28A>G p.S10G | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ETFRF1 | c.128del p.N43Tfs*4 | Frame Shift Del (DEL) | VAF 37/122 reads (30%) | called by mutect2, pindel, varscan2
- FBN2 | c.7240G>T p.G2414C | Missense Mutation (SNP) | VAF 174/481 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FBXW7 | c.664_667delinsAG p.R223Pfs*32 (on ENST00000281708 / NM_001349798.2; = p.R143Pfs*32 on NM_018315.5) | Frame Shift Del (DEL) | VAF 57/213 reads (27%) | called by pindel, varscan2*
- FCSK | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 137/349 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FMNL1 | c.240dup p.A81Rfs*23 | Frame Shift Ins (INS) | VAF 93/297 reads (31%) | called by mutect2, pindel, varscan2
- FOXO3 | c.212del p.G71Dfs*49 | Frame Shift Del (DEL) | VAF 61/203 reads (30%) | called by mutect2, pindel, varscan2
- FSIP2 | c.20722T>C p.*6908Rext*5 | Nonstop Mutation (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- FTO | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 127/293 reads (43%) | called by muse, mutect2, varscan2
- FZD4 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, varscan2
- GABRA6 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 136/403 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT7 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GLI3 | c.1978T>C p.S660P | Missense Mutation (SNP) | VAF 149/345 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GON4L | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 164/745 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPAM | c.1961G>A p.G654D | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR75 | c.719del p.P240Lfs*2 | Frame Shift Del (DEL) | VAF 83/224 reads (37%) | called by mutect2, pindel, varscan2
- GRIN2B | c.99del p.S34Afs*38 | Frame Shift Del (DEL) | VAF 70/198 reads (35%) | called by mutect2, pindel, varscan2
- GSTA3 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC1 | c.14137C>T p.P4713S | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGS | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HIVEP1 | c.6791A>G p.Q2264R | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HIVEP2 | c.1091_1092del p.T364Sfs*18 | Frame Shift Del (DEL) | VAF 62/196 reads (32%) | called by pindel, varscan2
- HOXA5 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 103/247 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- HSPB1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 189/497 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ICAM5 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGF1R | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IL3RA | c.898_901del p.N300Hfs*9 | Frame Shift Del (DEL) | VAF 93/252 reads (37%) | called by mutect2, pindel, varscan2
- IL6ST | c.5T>C p.L2S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INPPL1 | c.2337_2339del p.K779_S780delinsN | In Frame Del (DEL) | VAF 30/96 reads (31%) | called by mutect2, pindel, varscan2
- IRS2 | c.3965G>A p.S1322N | Missense Mutation (SNP) | VAF 116/311 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- IRX2 | c.305dup p.Y103Vfs*87 | Frame Shift Ins (INS) | VAF 50/210 reads (24%) | called by mutect2, pindel
- ITGA6 | c.276del p.P93Hfs*37 | Frame Shift Del (DEL) | VAF 181/384 reads (47%) | called by mutect2, varscan2
- JAK1 | c.2405_2408del p.K802Rfs*11 | Frame Shift Del (DEL) | VAF 58/132 reads (44%) | called by mutect2, pindel, varscan2
- JAM3 | c.240del p.F80Lfs*21 | Frame Shift Del (DEL) | VAF 104/323 reads (32%) | called by mutect2, pindel, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 39/93 reads (42%) | called by mutect2, pindel, varscan2
- JPH2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 186/415 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- JPH3 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 24/514 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- KEL | c.1969C>A p.H657N | Missense Mutation (SNP) | VAF 126/428 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF5B | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KISS1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 183/966 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KLHL13 | c.755G>A p.C252Y | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KLHL26 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KLHL29 | c.1008A>C p.E336D | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KMT2B | c.4498-1G>C p.X1500_splice | Splice Site (SNP) | VAF 58/141 reads (41%) | called by muse, mutect2, varscan2
- LAMA1 | c.9121A>G p.R3041G | Missense Mutation (SNP) | VAF 138/329 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LARP1 | c.911del p.P304Qfs*22 (on ENST00000518297 / NM_033551.3; = p.P227Qfs*22 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 96/255 reads (38%) | called by mutect2, pindel, varscan2
- LDLR | c.2530G>T p.G844C | Missense Mutation (SNP) | VAF 129/337 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMX1A | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 86/378 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRCH3 | c.997dup p.S333Ffs*12 | Frame Shift Ins (INS) | VAF 30/80 reads (38%) | called by mutect2, pindel, varscan2
- LYST | c.8494A>G p.S2832G | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAN2B1 | c.2178del p.K727Rfs*39 | Frame Shift Del (DEL) | VAF 181/475 reads (38%) | called by mutect2, pindel, varscan2
- MAP1B | c.3196A>G p.T1066A | Missense Mutation (SNP) | VAF 106/299 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARK3 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- MAST4 | c.2833A>G p.S945G (on ENST00000403625 / NM_001164664.2; = p.S756G on NM_015183.3) | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MDC1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 111/275 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- MEN1 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 214/542 reads (39%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MFN2 | c.2070-7T>C | Splice Region (SNP) | VAF 148/486 reads (30%) | called by muse, mutect2, varscan2
- MGRN1 | c.1283G>A p.C428Y | Missense Mutation (SNP) | VAF 149/370 reads (40%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- MIPEP | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MKNK2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MPHOSPH8 | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NAV3 | c.7153C>A p.L2385I (on ENST00000397909 / NM_001024383.2; = p.L2363I on NM_014903.6) | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NECAB1 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 95/234 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHS | c.1462del p.R488Gfs*68 | Frame Shift Del (DEL) | VAF 58/189 reads (31%) | called by mutect2, pindel, varscan2
- NOL6 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 109/329 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPR3 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUMA1 | c.25del p.A9Lfs*7 | Frame Shift Del (DEL) | VAF 82/236 reads (35%) | called by mutect2, varscan2
- NUP214 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2
- NUP42 | c.77G>T p.R26M | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 50/138 reads (36%) | called by mutect2, pindel, varscan2
- ORC1 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ORC5 | c.1029dup p.H344Tfs*25 | Frame Shift Ins (INS) | VAF 29/71 reads (41%) | called by mutect2, varscan2
- OTOG | c.5639del p.P1880Qfs*99 | Frame Shift Del (DEL) | VAF 107/347 reads (31%) | called by mutect2, pindel, varscan2
- P2RX2 | c.869C>A p.P290H (on ENST00000343948 / NM_170683.4; = p.P218H on NM_012226.5) | Missense Mutation (SNP) | VAF 105/286 reads (37%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P4HA2 | c.82+2T>A p.X28_splice | Splice Site (SNP) | VAF 63/159 reads (40%) | called by muse, mutect2, varscan2
- PAPOLA | c.958T>G p.Y320D | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PAPSS1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 132/343 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PBX3 | c.467T>C p.L156S | Missense Mutation (SNP) | VAF 79/190 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGA3 | c.2224G>T p.G742C | Missense Mutation (SNP) | VAF 219/569 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCK1 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 163/393 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE3A | c.2091del p.F697Lfs*3 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- PDPR | c.2341C>A p.L781I | Missense Mutation (SNP) | VAF 87/403 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PIGB | c.1151G>A p.W384* | Nonsense Mutation (SNP) | VAF 61/151 reads (40%) | called by muse, mutect2, varscan2
- PIGQ | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 82/223 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PIK3AP1 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 57/262 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITRM1 | c.2922G>T p.M974I | Missense Mutation (SNP) | VAF 102/338 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, varscan2
- PKP2 | c.752G>C p.S251T | Missense Mutation (SNP) | VAF 172/419 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- POU3F3 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 195/484 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- PPP4R3A | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRCC | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 82/392 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRIMPOL | c.658del p.S220Qfs*47 | Frame Shift Del (DEL) | VAF 88/295 reads (30%) | called by mutect2, pindel, varscan2
- PRMT3 | c.1345A>G p.T449A | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- PRMT6 | c.905A>C p.E302A | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.01); called by muse, mutect2
- PRR14 | c.836del p.P279Qfs*2 | Frame Shift Del (DEL) | VAF 31/94 reads (33%) | called by mutect2, pindel
- PTK7 | c.1320dup p.P441Tfs*35 | Frame Shift Ins (INS) | VAF 51/173 reads (29%) | called by mutect2, pindel, varscan2
- PTPN1 | c.1130del p.G377Efs*27 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | called by mutect2, pindel, varscan2
- PTPN13 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 128/345 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPN21 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 130/341 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPRQ | c.1045G>T p.G349* (on ENST00000616559; = p.G307* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 33/94 reads (35%) | called by muse, mutect2, varscan2
- RASAL2 | c.918A>T p.E306D | Missense Mutation (SNP) | VAF 47/283 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RBPJ | c.663del p.F221Lfs*42 | Frame Shift Del (DEL) | VAF 37/111 reads (33%) | called by mutect2, pindel, varscan2
- RFX1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 94/235 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RLIM | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK2 | c.412dup p.W138Lfs*12 | Frame Shift Ins (INS) | VAF 15/47 reads (32%) | called by mutect2, varscan2
- RPE | c.620G>T p.R207I (on ENST00000359429 / NM_001318926.1; = p.R157I on NM_006916.2) | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RPS6KA6 | c.2076T>G p.D692E | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SAGE1 | c.833dup p.N278Kfs*25 | Frame Shift Ins (INS) | VAF 30/130 reads (23%) | called by mutect2, pindel, varscan2
- SCO2 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 238/615 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SESN3 | c.269T>A p.L90* | Nonsense Mutation (SNP) | VAF 91/263 reads (35%) | called by muse, mutect2, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 40/58 reads (69%) | called by mutect2, varscan2
- SFXN3 | c.853del p.L285Cfs*14 | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | called by mutect2, pindel, varscan2
- SGK1 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHISA6 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 308/801 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SHLD2 | c.1285del p.T429Hfs*3 | Frame Shift Del (DEL) | VAF 30/123 reads (24%) | called by mutect2, varscan2
- SLC8A2 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- SLC9A2 | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLMAP | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMARCAD1 | c.1217A>G p.Q406R | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SORCS3 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 143/500 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SSC5D | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 122/334 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- STOX1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SVEP1 | c.9540del p.K3180Nfs*8 | Frame Shift Del (DEL) | VAF 103/299 reads (34%) | called by mutect2, pindel, varscan2
- SYNE1 | c.1903del p.M635Cfs*26 (on ENST00000367255 / NM_182961.4; = p.M642Cfs*26 on NM_033071.3) | Frame Shift Del (DEL) | VAF 138/439 reads (31%) | called by mutect2, pindel, varscan2
- SYNE2 | c.5005dup p.M1669Nfs*8 | Frame Shift Ins (INS) | VAF 60/194 reads (31%) | called by mutect2, pindel, varscan2
- SYNJ2 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 253/650 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAX1BP1 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); called by muse, mutect2
- TBC1D10B | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 97/233 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TERB1 | c.365_368del p.S122Ffs*18 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel
- THPO | c.1166G>T p.R389M (on ENST00000649095 / NM_001290003.1; = p.R249M on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.582); called by muse, mutect2
- TINAG | c.296dup p.S100Vfs*5 | Frame Shift Ins (INS) | VAF 55/165 reads (33%) | called by mutect2, pindel, varscan2
- TLK1 | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM119 | c.240del p.T81Pfs*7 | Frame Shift Del (DEL) | VAF 107/304 reads (35%) | called by mutect2, pindel, varscan2
- TMEM62 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- TRAV3 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TRIM41 | c.1806C>A p.H602Q | Missense Mutation (SNP) | VAF 154/335 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TRIM64C | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 131/330 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TRIM72 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRMT2A | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 86/304 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC37 | c.3758del p.N1253Ifs*4 | Frame Shift Del (DEL) | VAF 87/275 reads (32%) | called by mutect2, pindel, varscan2
- TTLL5 | c.1559_1561del p.A520del | In Frame Del (DEL) | VAF 36/98 reads (37%) | called by pindel, varscan2
- TTN | c.99470del p.K33157Sfs*12 (on ENST00000591111; = p.K25733Sfs*12 on NM_003319.4) | Frame Shift Del (DEL) | VAF 79/229 reads (34%) | called by pindel, varscan2
- TTN | c.78124A>G p.K26042E (on ENST00000591111; = p.K18618E on NM_003319.4) | Missense Mutation (SNP) | VAF 71/188 reads (38%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBE3B | c.183del p.F61Lfs*44 | Frame Shift Del (DEL) | VAF 23/86 reads (27%) | called by mutect2, pindel, varscan2
- UQCR10 | c.28T>A p.L10M | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- UQCRC2 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USP16 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- USP47 | c.1205G>T p.R402M (on ENST00000399455 / NM_001372095.1; = p.R314M on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13B | c.4130G>T p.S1377I | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZBTB1 | c.1571dup p.Q525Afs*4 | Frame Shift Ins (INS) | VAF 59/137 reads (43%) | called by mutect2, varscan2
- ZBTB11 | c.2626C>T p.H876Y | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBTB48 | c.1189A>G p.M397V | Missense Mutation (SNP) | VAF 18/408 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2
- ZFHX3 | c.6996dup p.C2333Mfs*2 | Frame Shift Ins (INS) | VAF 58/182 reads (32%) | called by mutect2, pindel, varscan2
- ZIC5 | c.497del p.P166Lfs*165 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | called by mutect2, pindel, varscan2
- ZNF292 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF449 | c.830del p.P277Qfs*8 | Frame Shift Del (DEL) | VAF 39/147 reads (27%) | called by mutect2, pindel, varscan2
- ZNFX1 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- AHNAK | c.14412G>A p.L4804= | Silent (SNP) | VAF 111/292 reads (38%) | called by muse, mutect2, varscan2
- ANHX | c.636G>A p.A212= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as rs565245948; called by muse, mutect2, varscan2
- APC2 | c.6129C>T p.C2043= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs1308241401; called by muse, mutect2, varscan2
- ARHGEF17 | c.5055G>A p.E1685= | Silent (SNP) | VAF 60/144 reads (42%) | catalogued as rs1016884567; called by mutect2, varscan2
- ASB4 | c.814C>T p.L272= | Silent (SNP) | VAF 85/238 reads (36%) | called by muse, mutect2, varscan2
- B3GNT9 | c.864C>T p.G288= | Silent (SNP) | VAF 57/154 reads (37%) | catalogued as rs1462443365; called by muse, mutect2, varscan2
- BRWD3 | c.5058C>T p.G1686= | Silent (SNP) | VAF 89/237 reads (38%) | catalogued as rs781010314; called by muse, mutect2, varscan2
- C10orf120 | c.549A>G p.L183= | Silent (SNP) | VAF 52/184 reads (28%) | called by muse, mutect2, varscan2
- C8B | c.660G>A p.T220= | Silent (SNP) | VAF 194/459 reads (42%) | catalogued as rs370360066; called by muse, mutect2, varscan2
- CAMK2D | c.477C>G p.G159= | Silent (SNP) | VAF 81/221 reads (37%) | called by muse, mutect2, varscan2
- CARMIL2 | c.1683G>A p.R561= | Silent (SNP) | VAF 107/255 reads (42%) | called by muse, mutect2, varscan2
- CBX8 | c.57G>A p.R19= | Silent (SNP) | VAF 79/215 reads (37%) | catalogued as rs1221350080; called by muse, mutect2, varscan2
- CD1E | c.849G>A p.L283= | Silent (SNP) | VAF 27/134 reads (20%) | called by muse, mutect2, varscan2
- CD81 | c.396G>A p.Q132= | Silent (SNP) | VAF 223/562 reads (40%) | called by muse, mutect2, varscan2
- CDC14B | c.132C>A p.P44= | Silent (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- CDC42BPB | c.3642C>T p.S1214= | Silent (SNP) | VAF 32/363 reads (9%) | called by muse, mutect2
- CDCA5 | c.396C>T p.D132= | Silent (SNP) | VAF 46/97 reads (47%) | catalogued as rs765815329, COSV51870761; called by muse, mutect2, varscan2
- CEBPB | c.603G>A p.A201= | Silent (SNP) | VAF 86/203 reads (42%) | catalogued as rs997116351; called by muse, mutect2, varscan2
- CEP350 | c.8976C>T p.N2992= | Silent (SNP) | VAF 25/157 reads (16%) | called by muse, mutect2, varscan2
- COL23A1 | c.402C>T p.D134= | Silent (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- COL4A6 | c.1248C>T p.G416= | Silent (SNP) | VAF 89/252 reads (35%) | called by muse, mutect2, varscan2
- COL9A2 | c.1350C>T p.P450= | Silent (SNP) | VAF 134/399 reads (34%) | catalogued as COSV65622262; called by muse, mutect2, varscan2
- CUEDC1 | c.468C>T p.I156= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs111753270; called by muse, mutect2, varscan2
- CYSLTR1 | c.471A>G p.P157= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs1204079251; called by muse, mutect2, varscan2
- DAXX | c.276G>A p.Q92= | Silent (SNP) | VAF 76/189 reads (40%) | catalogued as COSV56472142; called by muse, mutect2, varscan2
- DDB1 | c.2562G>A p.S854= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as rs771383564; called by muse, mutect2, varscan2
- DLL4 | c.999T>C p.C333= | Silent (SNP) | VAF 82/187 reads (44%) | catalogued as rs773508830; called by muse, mutect2, varscan2
- DLX4 | c.27C>T p.P9= | Silent (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- DST | c.11112G>A p.V3704= (on ENST00000361203 / NM_001374722.1; = p.V1292= on NM_015548.5) | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs772436994; called by muse, mutect2, varscan2
- DYNC1H1 | c.10518C>T p.D3506= | Silent (SNP) | VAF 203/524 reads (39%) | called by muse, mutect2, varscan2
- EPB41L4B | c.1381C>A p.R461= | Silent (SNP) | VAF 54/194 reads (28%) | called by muse, mutect2, varscan2
- FTMT | c.177C>A p.T59= | Silent (SNP) | VAF 61/140 reads (44%) | called by muse, mutect2, varscan2
- GAS2L3 | c.405T>C p.I135= | Silent (SNP) | VAF 85/222 reads (38%) | called by muse, mutect2, varscan2
- GPATCH4 | c.714T>C p.A238= | Silent (SNP) | VAF 98/462 reads (21%) | called by muse, mutect2, varscan2
- H4C1 | c.96G>A p.K32= | Silent (SNP) | VAF 69/206 reads (33%) | called by muse, mutect2, varscan2
- HCAR1 | c.657C>A p.T219= | Silent (SNP) | VAF 85/291 reads (29%) | catalogued as rs767155988; called by muse, mutect2, varscan2
- HECTD4 | c.10530G>A p.L3510= | Silent (SNP) | VAF 72/187 reads (39%) | catalogued as rs1202396543; called by muse, mutect2, varscan2
- HOXD9 | c.898C>T p.L300= | Silent (SNP) | VAF 55/192 reads (29%) | called by muse, mutect2, varscan2
- HTR1F | c.153C>T p.T51= | Silent (SNP) | VAF 128/347 reads (37%) | catalogued as COSV60390448; called by muse, mutect2, varscan2
- IBTK | c.2991C>T p.N997= | Silent (SNP) | VAF 46/116 reads (40%) | called by muse, mutect2, varscan2
- IGHE | c.381C>T p.F127= | Silent (SNP) | VAF 125/306 reads (41%) | catalogued as rs868912888; called by muse, mutect2, varscan2
- KBTBD11 | c.1644G>A p.T548= | Silent (SNP) | VAF 71/163 reads (44%) | called by muse, mutect2, varscan2
- KCNMA1 | c.1830C>T p.F610= | Silent (SNP) | VAF 109/419 reads (26%) | catalogued as rs202015764; called by muse, mutect2, varscan2
- KIZ | c.1248T>C p.A416= | Silent (SNP) | VAF 67/206 reads (33%) | called by muse, mutect2, varscan2
- KLHL34 | c.693C>T p.D231= | Silent (SNP) | VAF 82/211 reads (39%) | catalogued as rs981857318, COSV65278721; called by muse, mutect2, varscan2
- KRT39 | c.315G>A p.E105= | Silent (SNP) | VAF 91/278 reads (33%) | catalogued as COSV100842175; called by muse, mutect2, varscan2
- LRWD1 | c.1596C>G p.G532= | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as rs1195603578; called by muse, mutect2, varscan2
- LTBP2 | c.2856C>T p.Y952= | Silent (SNP) | VAF 242/586 reads (41%) | called by muse, mutect2, varscan2
- MAP2 | c.1566C>T p.T522= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs1202899945, COSV52286814; called by muse, mutect2, varscan2
- MAST4 | c.4398C>T p.H1466= (on ENST00000403625 / NM_001164664.2; = p.H1277= on NM_015183.3) | Silent (SNP) | VAF 117/269 reads (43%) | called by muse, mutect2, varscan2
- MED13 | c.5769T>C p.F1923= | Silent (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- MS4A15 | c.297C>T p.H99= (on ENST00000405633 / NM_001098835.2; = p.H6= on NM_152717.3) | Silent (SNP) | VAF 56/147 reads (38%) | called by muse, mutect2, varscan2
- NFAT5 | c.1680T>C p.S560= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs1031086836; called by muse, mutect2, varscan2
- NKX2-5 | c.300C>T p.P100= | Silent (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2
- NPAS3 | c.2076G>A p.P692= (on ENST00000356141 / NM_001164749.2; = p.P660= on NM_022123.3) | Silent (SNP) | VAF 67/184 reads (36%) | catalogued as rs1295093051, COSV60840889; called by muse, mutect2, varscan2
- NR4A2 | c.1119C>T p.V373= | Silent (SNP) | VAF 202/474 reads (43%) | catalogued as COSV59894390; called by muse, mutect2, varscan2
- OR2V2 | c.63C>T p.H21= | Silent (SNP) | VAF 75/205 reads (37%) | called by muse, mutect2, varscan2
- OTOF | c.5247C>T p.D1749= (on ENST00000272371 / NM_194248.3; = p.D982= on NM_004802.4) | Silent (SNP) | VAF 172/358 reads (48%) | catalogued as rs1340855486, COSV55505013; called by muse, varscan2
- OXR1 | c.1767T>C p.H589= (on ENST00000442977 / NM_001198532.1; = p.H588= on NM_018002.3) | Silent (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- PAK6 | c.141G>A p.L47= | Silent (SNP) | VAF 79/219 reads (36%) | called by muse, mutect2, varscan2
- PAOX | c.1116C>A p.A372= | Silent (SNP) | VAF 52/200 reads (26%) | catalogued as COSV53370990, COSV53372538; called by mutect2, varscan2
- PAPPA | c.3288C>T p.A1096= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs753006070, COSV60291461; called by muse, mutect2, varscan2
- PARP10 | c.2895G>A p.L965= | Silent (SNP) | VAF 16/442 reads (4%) | called by muse, mutect2
- PCDH17 | c.1518C>T p.T506= | Silent (SNP) | VAF 152/367 reads (41%) | called by muse, mutect2, varscan2
- PCDHB10 | c.1665C>T p.N555= | Silent (SNP) | VAF 143/497 reads (29%) | called by muse, mutect2, varscan2
- PHF23 | c.366C>A p.P122= | Silent (SNP) | VAF 89/240 reads (37%) | catalogued as COSV50038138; called by muse, mutect2, varscan2
- PIRT | c.186C>T p.G62= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as rs555559126, COSV74119824; called by muse, mutect2, varscan2
- PKD2 | c.180G>A p.R60= | Silent (SNP) | VAF 52/102 reads (51%) | catalogued as rs1263674695; ClinVar: likely benign; called by muse, mutect2
- PLEC | c.12642C>T p.N4214= (on ENST00000322810 / NM_201380.4; = p.N4104= on NM_000445.5) | Silent (SNP) | VAF 195/488 reads (40%) | catalogued as rs140538836, COSV59653873; called by muse, mutect2, varscan2
- PLXNA1 | c.2322C>T p.Y774= | Silent (SNP) | VAF 136/322 reads (42%) | catalogued as rs147176760; called by muse, mutect2, varscan2
- POPDC2 | c.789C>T p.R263= | Silent (SNP) | VAF 133/308 reads (43%) | catalogued as rs1283131215; called by muse, mutect2, varscan2
- PPP1R12B | c.960G>A p.E320= | Silent (SNP) | VAF 34/102 reads (33%) | called by muse, mutect2, varscan2
- PSEN2 | c.771C>T p.G257= | Silent (SNP) | VAF 84/352 reads (24%) | catalogued as rs7539017, COSV60916600; called by muse, mutect2, varscan2
- PTCH1 | c.3360G>A p.E1120= | Silent (SNP) | VAF 196/476 reads (41%) | catalogued as rs1554690458; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPN18 | c.1146C>T p.S382= | Silent (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.168C>T p.R56= | Silent (SNP) | VAF 19/208 reads (9%) | called by muse, mutect2
- RALBP1 | c.900G>A p.V300= | Silent (SNP) | VAF 75/196 reads (38%) | called by muse, mutect2, varscan2
- RALY | c.468G>A p.R156= (on ENST00000246194 / NM_016732.3; = p.R140= on NM_007367.4) | Silent (SNP) | VAF 78/207 reads (38%) | called by muse, mutect2, varscan2
- RBM15 | c.1221G>A p.R407= | Silent (SNP) | VAF 109/268 reads (41%) | catalogued as rs777680641; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.120G>A p.V40= | Silent (SNP) | VAF 44/183 reads (24%) | called by muse, mutect2, varscan2
- SASH1 | c.2667C>T p.D889= | Silent (SNP) | VAF 10/258 reads (4%) | called by muse, mutect2
- SETBP1 | c.819G>A p.T273= | Silent (SNP) | VAF 128/317 reads (40%) | catalogued as rs772700161, COSV56336632; called by muse, mutect2, varscan2
- SETBP1 | c.1431A>G p.S477= | Silent (SNP) | VAF 237/645 reads (37%) | called by muse, varscan2
- SLC4A7 | c.3234G>A p.P1078= | Silent (SNP) | VAF 51/207 reads (25%) | catalogued as rs747613260, COSV55403551; called by muse, mutect2, varscan2
- SLC5A9 | c.651G>A p.T217= | Silent (SNP) | VAF 86/223 reads (39%) | catalogued as rs61730938, COSV52581784, COSV99361310; called by muse, mutect2, varscan2
- SLC6A8 | c.1713C>T p.C571= | Silent (SNP) | VAF 19/605 reads (3%) | catalogued as rs782244505; ClinVar: benign / likely benign; called by muse, mutect2
- SNAP23 | c.255C>T p.C85= | Silent (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- SORBS1 | c.1173A>T p.S391= (on ENST00000361941 / NM_001034954.2; = p.S227= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/111 reads (54%) | called by muse, mutect2, varscan2
- SPEG | c.3678C>T p.H1226= | Silent (SNP) | VAF 126/328 reads (38%) | catalogued as rs1388099213; called by muse, mutect2, varscan2
- SSTR4 | c.378C>T p.D126= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as rs770914493, COSV54796826; called by muse, mutect2, varscan2
- STRA6 | c.417T>C p.T139= | Silent (SNP) | VAF 36/101 reads (36%) | called by muse, mutect2, varscan2
- TAPBPL | c.685C>T p.L229= | Silent (SNP) | VAF 153/384 reads (40%) | catalogued as rs1161833645; called by muse, mutect2, varscan2
- TECTA | c.285C>T p.F95= | Silent (SNP) | VAF 116/272 reads (43%) | catalogued as rs775584376, COSV50817729; called by muse, mutect2, varscan2
- TEX38 | c.216A>C p.R72= | Silent (SNP) | VAF 74/167 reads (44%) | called by muse, mutect2, varscan2
- TFRC | c.2094A>G p.R698= | Silent (SNP) | VAF 106/262 reads (40%) | called by muse, mutect2, varscan2
- THEMIS2 | c.1866G>A p.R622= | Silent (SNP) | VAF 44/128 reads (34%) | called by muse, mutect2
- TMTC2 | c.2394C>T p.A798= | Silent (SNP) | VAF 22/213 reads (10%) | catalogued as rs189664933, COSV100337843; called by muse, mutect2
- TRAPPC12 | c.762C>T p.P254= | Silent (SNP) | VAF 80/207 reads (39%) | catalogued as rs774631193; called by muse, mutect2, varscan2
- TRNAU1AP | c.849C>A p.I283= | Silent (SNP) | VAF 52/122 reads (43%) | called by muse, mutect2, varscan2
- TTN | c.73296A>G p.V24432= (on ENST00000591111; = p.V17008= on NM_003319.4) | Silent (SNP) | VAF 79/209 reads (38%) | catalogued as rs761647014; called by muse, mutect2, varscan2
- UPB1 | c.852C>T p.C284= | Silent (SNP) | VAF 177/458 reads (39%) | catalogued as rs781196303, COSV58116158; called by muse, mutect2, varscan2
- USH2A | c.8826C>T p.D2942= | Silent (SNP) | VAF 60/346 reads (17%) | catalogued as rs775823422; called by muse, mutect2, varscan2
- VEGFD | c.438C>T p.C146= | Silent (SNP) | VAF 77/169 reads (46%) | called by muse, mutect2, varscan2
- VGLL2 | c.666G>A p.P222= | Silent (SNP) | VAF 159/411 reads (39%) | called by muse, mutect2, varscan2
- WDR90 | c.2143C>T p.L715= | Silent (SNP) | VAF 150/396 reads (38%) | called by muse, mutect2, varscan2
- ZNF34 | c.117C>T p.D39= | Silent (SNP) | VAF 20/154 reads (13%) | catalogued as rs371444149; called by muse, mutect2
- ZNF544 | c.1680C>T p.N560= | Silent (SNP) | VAF 37/118 reads (31%) | called by muse, mutect2, varscan2
- ZNF644 | c.1824G>A p.L608= | Silent (SNP) | VAF 68/175 reads (39%) | called by muse, mutect2, varscan2
- ZNF850 | c.723T>C p.I241= | Silent (SNP) | VAF 52/156 reads (33%) | called by muse, mutect2, varscan2
- ZNF879 | c.1545A>G p.K515= | Silent (SNP) | VAF 11/144 reads (8%) | called by muse, mutect2
- AC107023.1 | chr12:40444462 G>A | 5'Flank (SNP) | VAF 61/155 reads (39%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-542-14097C>T | Intron (SNP) | VAF 74/187 reads (40%) | catalogued as rs1190788629; called by muse, mutect2, varscan2
- ADAM1A | n.1368C>T | RNA (SNP) | VAF 101/264 reads (38%) | called by muse, mutect2, varscan2
- AJAP1 | c.*5323C>T | 3'UTR (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- AK9 | c.1254+19_1254+22del | Intron (DEL) | VAF 6/51 reads (12%) | catalogued as rs770626634; called by mutect2, pindel, varscan2*
- ANXA8 | c.*181C>T | 3'UTR (SNP) | VAF 189/1126 reads (17%) | called by muse, varscan2
- ARHGEF25 | chr12:57620943 G>A | 3'Flank (SNP) | VAF 148/405 reads (37%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.4948+11575C>A | Intron (SNP) | VAF 53/151 reads (35%) | called by muse, mutect2, varscan2
- ARL13B | c.130+613del | Intron (DEL) | VAF 29/87 reads (33%) | called by mutect2, pindel, varscan2
- B3GALNT2 | c.113-1407G>A | Intron (SNP) | VAF 11/54 reads (20%) | catalogued as rs1383985581; called by muse, mutect2, varscan2
- CACNB1 | c.1332+23G>A | Intron (SNP) | VAF 95/242 reads (39%) | called by muse, mutect2, varscan2
- CDK5RAP3 | chr17:47971080 C>A | 5'Flank (SNP) | VAF 42/131 reads (32%) | called by muse, mutect2, varscan2
- CFAP52 | c.71-1461G>A | Intron (SNP) | VAF 29/89 reads (33%) | catalogued as rs867168009; called by muse, mutect2, varscan2
- COQ8A | c.*34A>T | 3'UTR (SNP) | VAF 103/448 reads (23%) | called by muse, mutect2, varscan2
- CTDSP1 | c.67+557G>A | Intron (SNP) | VAF 124/292 reads (42%) | catalogued as rs910857141; called by muse, mutect2, varscan2
- DDX11 | c.638+900G>A | Intron (SNP) | VAF 136/404 reads (34%) | catalogued as rs1215835829; called by muse, mutect2, varscan2
- DDX55 | c.1164+15G>A | Intron (SNP) | VAF 49/116 reads (42%) | catalogued as rs754189427; called by mutect2, varscan2
- DENND4B | c.-3dup | 5'UTR (INS) | VAF 14/75 reads (19%) | catalogued as rs770832731; called by mutect2, varscan2
- DOK6 | c.-36C>T | 5'UTR (SNP) | VAF 103/260 reads (40%) | catalogued as rs1218006178, COSV101235037; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.292-45T>G | Intron (SNP) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- EGFL6 | c.*50del | 3'UTR (DEL) | VAF 28/80 reads (35%) | catalogued as rs1446348498; called by mutect2, pindel
- EMC10 | c.679-266C>G | Intron (SNP) | VAF 40/130 reads (31%) | catalogued as rs779918120, COSV58541974; called by mutect2, varscan2
- ENAH | c.803-282del | Intron (DEL) | VAF 53/270 reads (20%) | called by mutect2, pindel, varscan2
- FAM181A | c.100-576C>T | Intron (SNP) | VAF 48/114 reads (42%) | called by muse, mutect2, varscan2
- FAS | c.*589C>T | 3'UTR (SNP) | VAF 63/296 reads (21%) | called by muse, mutect2, varscan2
- FMO6P | n.1375G>T | RNA (SNP) | VAF 70/445 reads (16%) | catalogued as rs1462308165; called by muse, mutect2, varscan2
- GLYCTK | c.-47G>C | 5'UTR (SNP) | VAF 39/132 reads (30%) | called by muse, mutect2, varscan2
- GNAS | c.2068+240C>T | Intron (SNP) | VAF 78/208 reads (38%) | catalogued as rs967732544; called by muse, mutect2, varscan2
- HEXD | c.*44del | 3'UTR (DEL) | VAF 89/254 reads (35%) | catalogued as rs751615819; called by mutect2, pindel, varscan2
- JAKMIP2 | c.2413-2775T>C | Intron (SNP) | VAF 64/169 reads (38%) | called by muse, mutect2, varscan2
- KCNC3 | c.*1385C>T | 3'UTR (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- KDM4C | c.2994+116del | Intron (DEL) | VAF 84/171 reads (49%) | catalogued as COSV67183745; called by mutect2, varscan2
- L3MBTL1 | c.1193-30C>T | Intron (SNP) | VAF 67/215 reads (31%) | catalogued as rs374464014; called by muse, mutect2, varscan2
- LRRC27 | chr10:132331751 ins C | 5'Flank (INS) | VAF 26/190 reads (14%) | called by mutect2, pindel, varscan2
- LRRC8D | c.-141C>T | 5'UTR (SNP) | VAF 59/200 reads (30%) | called by muse, mutect2, varscan2
- MAPRE3 | c.267+106G>A | Intron (SNP) | VAF 20/48 reads (42%) | catalogued as rs767804788; called by muse, mutect2
- MDFIC | c.-7G>A | 5'UTR (SNP) | VAF 96/217 reads (44%) | catalogued as rs930922489; called by muse, mutect2, varscan2
- MS4A6A | c.651+10C>T | Intron (SNP) | VAF 109/253 reads (43%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40421242 del A | 3'Flank (DEL) | VAF 13/28 reads (46%) | catalogued as rs746639059; called by mutect2, pindel, varscan2
- MUCL3 | c.946+868A>G | Intron (SNP) | VAF 69/338 reads (20%) | catalogued as rs1305952989, COSV58516256; called by muse, mutect2, varscan2
- NAPA | c.561+148del | Intron (DEL) | VAF 46/128 reads (36%) | catalogued as rs1349876274; called by mutect2, varscan2
- NEK7 | c.198+3306del | Intron (DEL) | VAF 14/72 reads (19%) | catalogued as rs749732874; called by mutect2, pindel, varscan2
- NLRC5 | c.4154+205G>T | Intron (SNP) | VAF 52/154 reads (34%) | catalogued as rs1295311548; called by muse, mutect2, varscan2
- NRIP3 | c.*612G>A | 3'UTR (SNP) | VAF 41/98 reads (42%) | catalogued as rs1339089593, COSV100487129; called by muse, mutect2, varscan2
- OGFOD1 | c.301-20del | Intron (DEL) | VAF 48/133 reads (36%) | catalogued as rs771823733; called by mutect2, varscan2
- OR7A2P | n.362G>A | RNA (SNP) | VAF 55/186 reads (30%) | catalogued as rs528570028; called by muse, mutect2, varscan2
- PADI1 | c.*96dup | 3'UTR (INS) | VAF 185/552 reads (34%) | called by mutect2, pindel, varscan2
- PCSK4 | c.1391+15C>T | Intron (SNP) | VAF 54/139 reads (39%) | catalogued as rs539574874; called by muse, mutect2, varscan2
- PHYKPL | c.59+17C>T | Intron (SNP) | VAF 47/110 reads (43%) | catalogued as rs749198645; called by muse, mutect2, varscan2
- PI4KAP2 | n.2831C>A | RNA (SNP) | VAF 78/208 reads (38%) | called by muse, varscan2
- PITRM1 | c.2646-904C>T | Intron (SNP) | VAF 45/147 reads (31%) | catalogued as rs919528512; called by muse, mutect2, varscan2
- PLEKHD1 | c.243+99C>T | Intron (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- POPDC2 | c.1009+84del | Intron (DEL) | VAF 28/87 reads (32%) | called by mutect2, pindel, varscan2
- PRKCB | c.-5G>A | 5'UTR (SNP) | VAF 129/325 reads (40%) | called by muse, mutect2, varscan2
- PRRC2C | c.8199+1071G>A | Intron (SNP) | VAF 121/476 reads (25%) | called by muse, mutect2, varscan2
- PUS10 | c.126+907C>T | Intron (SNP) | VAF 63/177 reads (36%) | called by muse, mutect2, varscan2
- RAB26 | c.307-380T>G | Intron (SNP) | VAF 57/147 reads (39%) | called by muse, mutect2, varscan2
- RNF14 | chr5:141991892 G>A | 3'Flank (SNP) | VAF 77/179 reads (43%) | called by muse, mutect2, varscan2
- RNF220 | c.1630-10C>G | Intron (SNP) | VAF 73/281 reads (26%) | called by muse, mutect2, varscan2
- RPL28 | c.205+160_205+162del | Intron (DEL) | VAF 37/104 reads (36%) | catalogued as rs750063282; called by mutect2, pindel, varscan2
- SCN4B | c.*317G>A | 3'UTR (SNP) | VAF 195/515 reads (38%) | catalogued as rs1431822176; called by muse, mutect2, varscan2
- SLAMF8 | chr1:159837959 C>T | 3'Flank (SNP) | VAF 98/489 reads (20%) | called by muse, mutect2, varscan2
- SNAP47 | c.1249-4721G>A | Intron (SNP) | VAF 59/318 reads (19%) | catalogued as rs566590122; called by muse, mutect2, varscan2
- SNW1 | c.1413-30T>A | Intron (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- SRD5A3 | c.-33dup | 5'UTR (INS) | VAF 47/158 reads (30%) | called by mutect2, pindel, varscan2
- STAB1 | c.4364-40del | Intron (DEL) | VAF 45/119 reads (38%) | called by mutect2, pindel, varscan2
- STK26 | c.-148G>A | 5'UTR (SNP) | VAF 22/332 reads (7%) | catalogued as COSV100688538; called by muse, mutect2
- UBR2 | c.1281+157G>A | Intron (SNP) | VAF 55/149 reads (37%) | catalogued as rs978399522; called by muse, mutect2, varscan2
- ZDHHC23 | c.1217-20del | Intron (DEL) | VAF 19/56 reads (34%) | catalogued as rs767083235; called by mutect2, varscan2
- ZFHX4 | c.3093+97del | Intron (DEL) | VAF 41/96 reads (43%) | catalogued as rs751858242; called by mutect2, varscan2
- ZNF252P | n.245+3153del | Intron (DEL) | VAF 16/35 reads (46%) | called by mutect2, pindel, varscan2
- ZRANB3 | c.1206+399del | Intron (DEL) | VAF 37/121 reads (31%) | called by mutect2, pindel, varscan2
